Surgical pathology report (de-identified scan), TCGA case TCGA-06-2567, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-2567-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

CGA-06-2567

CLINICAL HISTORY

Brain tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Left Temporal tumoe, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, left temporal tumor, excision: Consistent with recurrent/residual glioblastoma (see comment).

COMMENT

Sections show cerebral cortex with necrosis, foamy macrophages and vascular proliferation consistent with treatment effect. In a few small focal areas pleomorphic atypical glial cells without discernible cytoplasm are infiltrating the cortex. The latter cells are consistent with recurrent/residual glioma cells and demonstrate strong diffuse p53 positivity and a very high MIB-1 labeling index of approximately 80 to 90%.

GROSS DESCRIPTION

A. Left Temporal tumoe, excision biopsy: CONTAINER LABEL: Left temporal tumor.

FIXATIVE: Formalin. NO. PIECES: 1, red-tan brain tissue covered on one side by gray-tan leptomeninges. SIZE/VOL: 2.5 x 1.7 x 1.0 cm and 2.08 grams

CASSETTES: 2, [REDACTED]

ICD-9(s):

91.9 191.9

[page 2 of 2]
Histo Data

Part A: Left Temporal tumoe, excision biopsy

taken:	Received:		
tain/	Block	Ordered	Comment
H/E x 1	1		
Rct 1 H/E x 1	1		
H/E x 1	2		
MIB1-DA x 1	2		
P53DO7 x 1	2		
Rct 2 H/E x 1	2		

*** End of Report ***

Source: NCI Genomic Data Commons file 92833302-e943-4944-9835-fbf0bdc08892 (TCGA-06-2567.455CACE9-E0B5-4A2B-9E90-DB88ED14F11B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).